Somatic mutation profile of tumor specimen 0DFO1J from CCDI case PBBSJU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 14.1 years (5,145 days).
Specimen 0DFO1J: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e84a970-655e-4524-b746-54336164bbbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFO16 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/829e15ee-b2d8-4bdf-b453-9bdfcf142f10

The open-access MAF lists 1,390 somatic variants for this specimen: 825 protein-altering or splice-affecting, 324 silent, 241 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 730, Silent 324, Intron 137, 3'UTR 60, Nonsense Mutation 38, Splice Site 36, 5'UTR 29, Splice Region 17, 5'Flank 7, RNA 6, Translation Start Site 4, 3'Flank 2.

Variants (750 of 1,390; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5128+2T>C p.X1710_splice (on ENST00000272895 / NM_173076.3; = p.X1392_splice on NM_015657.3) | Splice Site (SNP) | VAF 80/204 reads (39%) | catalogued as rs1553523630; ClinVar: likely pathogenic; called by muse, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 140/362 reads (39%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, varscan2
- B2M | c.68-2A>G p.X23_splice | Splice Site (SNP) | VAF 162/236 reads (69%) | hotspot (GDC flag); catalogued as rs111482205, COSV62562974, COSV62564351; called by muse, varscan2
- BRCA2 | c.9382C>T p.R3128* | Nonsense Mutation (SNP) | VAF 268/526 reads (51%) | catalogued as rs80359212, CM014328, COSV66461429; ClinVar: pathogenic; called by muse, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 86/286 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, varscan2
- GABRB2 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1554093884, COSV50956265; ClinVar: likely pathogenic; called by muse, varscan2
- GANAB | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs879255643, CM166313, COSV55488196; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 82/232 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SRCAP | c.7303C>T p.R2435* | Nonsense Mutation (SNP) | VAF 60/304 reads (20%) | catalogued as rs199469465, CM121173; ClinVar: pathogenic; called by muse, varscan2
- THRA | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.623); catalogued as rs1555545033, CM147326, COSV99225882; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 98/244 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- A2ML1 | c.3207C>G p.N1069K | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV100228474; called by muse, varscan2
- ABCB6 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1436080788, COSV54693869, COSV54694307; called by muse, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- ACKR4 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs773236595; called by muse, varscan2
- ADAM33 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100598154; called by muse, varscan2
- ADAMTS1 | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53173383; called by muse, varscan2
- ADAMTS14 | c.2950T>C p.C984R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941477; called by muse, varscan2
- ADAMTSL3 | c.2194C>T p.H732Y | Missense Mutation (SNP) | VAF 98/243 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1042076363, COSV99719806; called by muse, varscan2
- ADCY10 | c.4615C>T p.R1539W | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs150827904; called by muse, varscan2
- ADGRB1 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 96/262 reads (37%) | catalogued as rs371544443, COSV60103429; called by muse, varscan2
- AFAP1L1 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs771890549; called by muse, varscan2
- AK1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs767893823; called by muse, varscan2
- AKNA | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs372030820, COSV56313556; called by muse, varscan2
- ALG2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as rs201729325; called by muse, varscan2
- ANO8 | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV50173521; called by muse, varscan2
- ANO8 | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs139768548; called by muse, varscan2
- APLF | c.1321A>G p.N441D | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1226969607; called by muse, varscan2
- APOB | c.10018G>T p.D3340Y | Missense Mutation (SNP) | VAF 67/359 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51949588; called by muse, varscan2
- APOC2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs750370010, COSV52990404, COSV52990576; called by muse, varscan2
- ARAP3 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as rs372101887, COSV53355287; called by muse, varscan2
- ARHGAP32 | c.5989G>A p.V1997M (on ENST00000310343 / NM_001378025.1; = p.V1648M on NM_014715.4) | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs141193303; called by muse, varscan2
- ARHGAP45 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs1206900299; called by muse, varscan2
- ARID2 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100535293; called by muse, varscan2
- ARL4C | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs1162856363; called by muse, varscan2
- ARL8B | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV56578649; called by muse, varscan2
- ASPM | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1462284532; called by muse, varscan2
- ATM | c.1748A>G p.Y583C | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs587780614, COSV53753989; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- ATP1A3 | c.799C>T p.R267C (on ENST00000545399 / NM_001256214.2; = p.R254C on NM_152296.5) | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs782783739; called by muse, varscan2
- ATP2A2 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.247); catalogued as rs780418333; called by muse, varscan2
- ATP6V0D2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 142/409 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.417); catalogued as rs537083185; called by muse, varscan2
- ATP6V1H | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs756445508; called by muse, varscan2
- B4GALNT4 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.876); catalogued as rs770437353; called by muse, varscan2
- BCAR3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs370836321, COSV99550485; called by muse, varscan2
- BEAN1 | c.288C>T p.Y96= | Splice Region (SNP) | VAF 102/323 reads (32%) | catalogued as rs1168621983; called by muse, varscan2
- BICC1 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs139220902; called by muse, varscan2
- BMP1 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs752336261; called by muse, varscan2
- BMPER | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as rs1366041572, COSV99779263; called by muse, varscan2
- BTBD17 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs547585948, COSV64730450; called by muse, varscan2
- C16orf86 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV99708195; called by muse, varscan2
- C18orf63 | c.1867A>G p.S623G | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1398023083; called by muse, varscan2
- C3AR1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203248934, COSV99368864, COSV99369075; called by muse, varscan2
- C3orf20 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs746614346, COSV99513596; called by muse, varscan2
- C5orf22 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 131/394 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs755393777, COSV57598218; called by muse, varscan2
- CACNA1A | c.6631C>T p.R2211W | Missense Mutation (SNP) | VAF 220/588 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs780467849; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1C | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771393283; called by muse, varscan2
- CAPN3 | c.409T>G p.C137G | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as CM990298; called by muse, varscan2
- CARNS1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 124/353 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs756772834, COSV57051416; called by muse, varscan2
- CCDC127 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs559771861, COSV99722994; called by muse, varscan2
- CCDC180 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs550069242; called by muse, varscan2
- CCDC188 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 127/336 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as rs1421050581; called by muse, varscan2
- CCND2 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746043858, COSV54224552; called by muse, varscan2
- CDH23 | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs373422805; called by muse, varscan2
- CDH26 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554586698, COSV54848129; called by muse, varscan2
- CEP192 | c.5837T>C p.I1946T | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1251389575; called by muse, varscan2
- CEP89 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 96/245 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs772350734; called by muse, varscan2
- CEP89 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775079961, COSV59863840; called by muse, varscan2
- CFAP57 | c.3203G>A p.R1068Q (on ENST00000372492 / NM_001378189.1; = p.R1101Q on NM_001195831.3) | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1388472093; called by muse, varscan2
- CFH | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1300493671, COSV62776836; called by muse, varscan2
- CGGBP1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as rs1350839978, COSV58851580; called by muse, varscan2
- CHD9 | c.2512-6A>G | Splice Region (SNP) | VAF 22/165 reads (13%) | catalogued as rs944267610; called by muse, varscan2
- CHRNA10 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs57652919; called by muse, varscan2
- CIC | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs185110849; called by muse, varscan2
- CIC | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 126/368 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50549905, COSV50559779; called by muse, varscan2
- CIITA | c.3154T>C p.Y1052H | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1439344870; called by muse, varscan2
- CKMT1B | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 159/434 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747021769; called by muse, varscan2
- CLCNKB | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 134/408 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs149940233, COSV100989757; called by muse, varscan2
- CLSTN1 | c.880G>A p.E294K (on ENST00000377298 / NM_001009566.3; = p.E284K on NM_014944.4) | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs1480817241, COSV63648195; called by muse, varscan2
- CMTM2 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 141/368 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs149370651; called by muse, varscan2
- CNDP2 | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60840101, COSV60841702; called by muse, varscan2
- CNGA4 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV66005273, COSV66005813; called by muse, varscan2
- CNOT1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 126/348 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs756274247; called by muse, varscan2
- CNTN5 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs201089460, COSV54321916; called by muse, varscan2
- CNTN6 | c.823T>G p.Y275D | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV63193421; called by muse, varscan2
- COL4A6 | c.5039G>A p.R1680Q | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs773301536; called by muse, varscan2
- COL6A2 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.441); catalogued as rs751410120; ClinVar: uncertain significance; called by muse, varscan2
- CPA4 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 64/154 reads (42%) | catalogued as rs1350070048, COSV55982944; called by muse, varscan2
- CPD | c.2732C>T p.A911V | Missense Mutation (SNP) | VAF 142/481 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs946222162; called by muse, varscan2
- CR2 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772503117, COSV65505978; ClinVar: uncertain significance; called by muse, varscan2
- CRAT | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV58879147; called by muse, varscan2
- CREB5 | c.445T>C p.S149P (on ENST00000357727 / NM_182898.4; = p.S142P on NM_004904.3) | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs75512111; called by muse, varscan2
- CREBBP | c.5024A>G p.H1675R | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52139255; called by muse, varscan2
- CROCC2 | c.4132C>T p.R1378W | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as rs1191976514; called by muse, varscan2
- CRTC1 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs1014782697; called by muse, varscan2
- CRYAB | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs876657444; ClinVar: likely benign; called by muse, varscan2
- CUL7 | c.3253C>T p.R1085C | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373931860; called by muse, varscan2
- CUX1 | c.4352G>A p.R1451H | Missense Mutation (SNP) | VAF 118/344 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs782575248; called by muse, varscan2
- CWH43 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 112/312 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs371671107; called by muse, varscan2
- CYB5R4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs139757506; called by muse, varscan2
- CYFIP2 | c.2865G>T p.E955D (on ENST00000616178 / NM_001291722.2; = p.E930D on NM_014376.4) | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.848); catalogued as COSV59041233; called by muse, varscan2
- CYP21A2 | c.770T>C p.M257T | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as rs762929624; called by muse, varscan2
- CYP2C9 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 194/546 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99582476; called by muse, varscan2
- CYP46A1 | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs763189041; called by muse, varscan2
- DAB2IP | c.2189C>T p.S730L (on ENST00000408936; = p.S702L on NM_032552.3) | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760499189; called by muse, varscan2
- DCHS1 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759188370, COSV55032458; called by muse, varscan2
- DCLK3 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 128/396 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as rs202208144; called by muse, varscan2
- DFFA | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.054); catalogued as COSV65477128; called by muse, varscan2
- DGKD | c.2125C>T p.R709W (on ENST00000264057 / NM_152879.3; = p.R665W on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1050715721; called by muse, varscan2
- DHODH | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs770520210; called by muse, varscan2
- DHX37 | c.3319C>T p.R1107* | Nonsense Mutation (SNP) | VAF 69/163 reads (42%) | catalogued as rs780808803; called by muse, varscan2
- DNAH2 | c.6541G>A p.V2181I | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs147226714; called by muse, varscan2
- DOCK6 | c.4960G>A p.V1654M | Missense Mutation (SNP) | VAF 157/414 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs772437948; called by muse, varscan2
- DOCK7 | c.2854A>G p.T952A | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs931119441; called by muse, varscan2
- DST | c.2086C>T p.R696W (on ENST00000361203 / NM_001374722.1; = p.R370W on NM_001723.6) | Missense Mutation (SNP) | VAF 121/369 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs775464446, COSV55023324; ClinVar: uncertain significance; called by muse, varscan2
- ECT2L | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 69/176 reads (39%) | catalogued as rs753798507, COSV62887690; called by muse, varscan2
- EGFLAM | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs1420975360; called by muse, varscan2
- EIF3A | c.2539C>T p.R847W | Missense Mutation (SNP) | VAF 132/357 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs762760258; called by muse, varscan2
- EMC10 | c.678+1G>A p.X226_splice | Splice Site (SNP) | VAF 16/126 reads (13%) | catalogued as rs752673575; called by muse, varscan2
- EML3 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs965321691; called by muse, varscan2
- EPB41 | c.1276A>G p.K426E (on ENST00000343067 / NM_001166005.2; = p.K217E on NM_004437.4) | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs563336446; called by muse, varscan2
- EPM2AIP1 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1210567713; called by muse, varscan2
- ERGIC1 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV58595744; called by muse, varscan2
- ERICH6B | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 176/325 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs764874398; called by muse, varscan2
- ESPL1 | c.5015G>A p.R1672H | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs200673617, COSV99229310; called by muse, varscan2
- EVC2 | c.3888G>T p.L1296F | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60395934; called by muse, varscan2
- EXOC7 | c.1567A>G p.M523V (on ENST00000335146 / NM_001145297.4; = p.M441V on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs138305534; called by muse, varscan2
- FAM124A | c.487C>T p.R163W (on ENST00000322475 / NM_001242312.2; = p.R199W on NM_145019.4) | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758162138, COSV54474974; called by muse, varscan2
- FAM161B | c.715C>T p.R239C (on ENST00000651776; = p.R176C on NM_152445.3) | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs753056615; called by muse, varscan2
- FAM178B | c.1877T>C p.M626T (on ENST00000490605 / NM_001122646.3; = p.M66T on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.114); catalogued as COSV59971267; called by muse, varscan2
- FAM214A | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs757550997, COSV55922683; called by muse, varscan2
- FAM234A | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs755791137, COSV56992983; called by muse, varscan2
- FAM47A | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 119/165 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV60497611; called by muse, varscan2
- FAM53C | c.274T>G p.F92V | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1286126620; called by muse, varscan2
- FAM71C | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746189188, COSV100175742; called by muse, varscan2
- FAM86B2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs1186184532; called by muse, varscan2
- FANCA | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs767092317; ClinVar: uncertain significance; called by muse, varscan2
- FASN | c.6130A>G p.I2044V | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs375139880; ClinVar: uncertain significance; called by muse, varscan2
- FAT3 | c.9193C>T p.R3065* | Nonsense Mutation (SNP) | VAF 116/304 reads (38%) | catalogued as COSV53082790; called by muse, varscan2
- FERMT1 | c.2028G>T p.Q676H | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.732); catalogued as COSV99452321; called by muse, varscan2
- FFAR3 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 128/805 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs745858408, COSV59908982; called by muse, varscan2
- FMNL3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs754025129; called by muse, varscan2
- FOXE1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1158636786; called by muse, varscan2
- FXR2 | c.1768C>A p.R590S | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100001979; called by muse, varscan2
- GALNT10 | c.1591A>G p.S531G | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV51725742; called by muse, varscan2
- GALNT17 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974898586, COSV61155556; called by muse, varscan2
- GALT | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 213/562 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs111033750, CM074201; ClinVar: uncertain significance; called by muse, varscan2
- GASK1A | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 150/420 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383406312; called by muse, varscan2
- GATM | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 148/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768118194; ClinVar: uncertain significance; called by muse, varscan2
- GBE1 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771447249; called by muse, varscan2
- GC | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs750468115; called by muse, varscan2
- GIT1 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs746705525; called by muse, varscan2
- GJB4 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs754364013; called by muse, varscan2
- GLIS3 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.561); catalogued as rs769890708; called by muse, varscan2
- GNAS | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs1264272338, COSV58336352; called by muse, varscan2
- GOLGA6L10 | c.1462A>G p.S488G | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs2436245; called by muse, varscan2
- GOT1 | c.1102+1G>A p.X368_splice | Splice Site (SNP) | VAF 134/326 reads (41%) | catalogued as rs1300449801, COSV104423554; called by muse, varscan2
- GPAT4 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV104431136; called by muse, varscan2
- GPR137 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs149851257; called by muse, varscan2
- GPR161 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); catalogued as rs1001678771, COSV54790146; called by muse, varscan2
- GPR85 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 174/485 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as rs756442417, COSV51782887; called by muse, varscan2
- GPRIN2 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65401767; called by muse, varscan2
- GPX3 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs373981887; called by muse, varscan2
- GREM2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV58947365; called by muse, varscan2
- GRIA4 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as rs369753546; called by muse, varscan2
- GRID2IP | c.2488G>A p.V830I | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773330756, COSV70692820; called by muse, varscan2
- GRIN2A | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs969233060; called by muse, varscan2
- GRK1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 222/426 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746360692, COSV59552915; called by muse, varscan2
- GRK1 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 77/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886412350; called by muse, varscan2
- GSK3A | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 108/290 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.47); catalogued as rs748311925; called by muse, varscan2
- H4C13 | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 96/327 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs148131091; called by muse, varscan2
- HCN1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV57537310, COSV57542378; called by muse, varscan2
- HDAC9 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs752243588, COSV101286736; called by muse, varscan2
- HECTD4 | c.6883A>G p.S2295G | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs1566079234; called by muse, varscan2
- HEPACAM | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 128/367 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as rs149730492; called by muse, varscan2
- HHEX | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs1295181822; called by muse, varscan2
- HSPG2 | c.11732G>A p.R3911H | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778569997; called by muse, varscan2
- HSPG2 | c.7165G>A p.G2389S | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765181959; ClinVar: uncertain significance; called by muse, varscan2
- HYOU1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68215718; called by muse, varscan2
- IFNA7 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs779461917; called by muse, varscan2
- IGSF9 | c.2084G>A p.R695H (on ENST00000368094 / NM_001135050.2; = p.R679H on NM_020789.4) | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765405500; called by muse, varscan2
- IKBKB | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 58/164 reads (35%) | catalogued as rs912645794, COSV100645589; called by muse, varscan2
- IKZF4 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56271977; called by muse, varscan2
- IL31RA | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 118/292 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs147957239; called by muse, varscan2
- INCENP | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs770503094, COSV99611044; called by muse, varscan2
- IRGQ | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as rs1373117947, COSV60670496; called by muse, varscan2
- ITGA8 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs146740446; called by muse, varscan2
- JADE1 | c.2347C>T p.R783* | Nonsense Mutation (SNP) | VAF 78/192 reads (41%) | catalogued as rs757153915; called by muse, varscan2
- KANK2 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs147297854; called by muse, varscan2
- KAT2B | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 86/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs754096979, COSV55429522; called by muse, varscan2
- KCNH1 | c.2480G>A p.G827D (on ENST00000271751 / NM_172362.3; = p.G800D on NM_002238.4) | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs764030459; called by muse, varscan2
- KCNH1 | c.2159G>A p.R720H (on ENST00000271751 / NM_172362.3; = p.R693H on NM_002238.4) | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.302); catalogued as rs745766834, COSV55085748; called by muse, varscan2
- KCNJ11 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775204908, CM152364, COSV100379253; called by muse, varscan2
- KCTD21 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 38/168 reads (23%) | catalogued as rs757080401, COSV60740934; called by muse, varscan2
- KDM4C | c.2356C>T p.R786* | Nonsense Mutation (SNP) | VAF 74/240 reads (31%) | catalogued as rs374516052; called by muse, varscan2
- KIF14 | c.2647C>T p.R883C | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs150001112; called by muse, varscan2
- KIF1C | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1472733846; called by muse, varscan2
- KIF22 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149549504; called by muse, varscan2
- KIF23 | c.1463T>C p.I488T | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV99531748; called by muse, varscan2
- KIF26A | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1258828679; called by muse, varscan2
- KIF26A | c.4447G>A p.G1483S | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs775132075, COSV59465587; called by muse, varscan2
- KL | c.2731G>A p.G911R | Missense Mutation (SNP) | VAF 312/558 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777451765, COSV66310398; called by muse, varscan2
- KLF18 | c.2752A>G p.M918V | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1476542909; called by muse, varscan2
- KLF4 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65928660; called by muse, varscan2
- KMT2C | c.8879C>T p.P2960L | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.632); catalogued as rs142287778; called by muse, varscan2
- KNDC1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.962); catalogued as rs778600479, COSV58842713; called by muse, varscan2
- KRT4 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774011441; called by muse, varscan2
- LAMA5 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as rs996558386; called by muse, varscan2
- LAMB2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1197492912; called by muse, varscan2
- LAMC3 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 132/338 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs143795459; called by muse, varscan2
- LAMP3 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 101/307 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs570150710, COSV55615534; called by muse, varscan2
- LCMT2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs771392913, COSV59791801; called by muse, varscan2
- LDB3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 134/340 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs751254270, COSV53941118, COSV53950284; ClinVar: uncertain significance; called by muse, varscan2
- LMTK2 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 142/378 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs755793023; called by muse, varscan2
- LRRC36 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 86/313 reads (27%) | catalogued as rs139430099; called by muse, varscan2
- LRRC8E | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60717414; called by muse, varscan2
- LRRC8E | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs764336589, COSV60718862; called by muse, varscan2
- LRRN1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs964412635, COSV60013408; called by muse, varscan2
- LUC7L | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778917081; called by muse, varscan2
- MAGI1 | c.3085C>T p.R1029W (on ENST00000402939 / NM_001033057.2; = p.R1058W on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201650657; called by muse, varscan2
- MAP2K7 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV67608956; called by muse, varscan2
- MAP3K10 | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1456262756; called by muse, varscan2
- MAP3K21 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64045555; called by muse, varscan2
- MAP4K4 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746600320; called by muse, varscan2
- MAPKBP1 | c.2617C>T p.R873W (on ENST00000456763 / NM_001128608.2; = p.R867W on NM_014994.3) | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199670186; called by muse, varscan2
- MCOLN1 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1251912873; called by muse, varscan2
- MECOM | c.442C>T p.R148W (on ENST00000468789 / NM_001105078.4; = p.R336W on NM_004991.4) | Missense Mutation (SNP) | VAF 110/304 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150819501; called by muse, varscan2
- MEGF8 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs755656068; called by muse, varscan2
- METTL16 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200997068; called by muse, varscan2
- MKRN1 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1357580673; called by muse, varscan2
- MLF1 | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs757816819; called by muse, varscan2
- MPDZ | c.4321G>A p.V1441I | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.861); catalogued as rs535598404; called by muse, varscan2
- MPPE1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs553789724, COSV100013380; called by muse, varscan2
- MRGPRF | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274824700, COSV57995817; called by muse, varscan2
- MSANTD1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173252632; called by muse, varscan2
- MSL1 | c.1339C>T p.R447W (on ENST00000398532 / NM_001365919.1; = p.R184W on NM_001012241.2) | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs1475222912; called by muse, varscan2
- MTHFSD | c.62T>C p.M21T (on ENST00000360900 / NM_001159377.2; = p.M20T on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/330 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV59802378; called by muse, varscan2
- MUC4 | c.12859T>A p.S4287T (on ENST00000463781 / NM_018406.7; = p.S51T on NM_004532.6) | Missense Mutation (SNP) | VAF 123/330 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); catalogued as COSV57783858; called by muse, varscan2
- MUS81 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 116/319 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs766623994, COSV57261462; called by muse, varscan2
- MYBPC3 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756102881, COSV57024938; ClinVar: uncertain significance; called by muse, varscan2
- MYCBP2 | c.6725G>A p.R2242H (on ENST00000357337; = p.R2280H on NM_015057.5) | Missense Mutation (SNP) | VAF 180/366 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs151088212; called by muse, varscan2
- MYH13 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367783054; called by muse, varscan2
- MYO1D | c.2278G>A p.V760M | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs769405180; called by muse, varscan2
- MYOZ1 | c.825G>A p.W275* | Nonsense Mutation (SNP) | VAF 98/316 reads (31%) | catalogued as rs1176061577; called by muse, varscan2
- NAA25 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs972618736; called by muse, varscan2
- NCAPD3 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs551193021, COSV101596367; called by muse, varscan2
- NEDD4L | c.1534C>T p.R512W (on ENST00000400345 / NM_001144967.3; = p.R492W on NM_015277.6) | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56846740; called by muse, varscan2
- NELFE | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs542263058; called by muse, varscan2
- NIN | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 106/303 reads (35%) | catalogued as rs1342714248; called by muse, varscan2
- NRBP1 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 170/492 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs769914699; called by muse, varscan2
- NRXN1 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs778031536, COSV58461473; called by muse, varscan2
- NRXN3 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750343246, COSV59751358; called by muse, varscan2
- NXPE3 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1187660677; called by muse, varscan2
- OARD1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as COSV104391474; called by muse, varscan2
- OBSCN | c.13262C>T p.T4421M | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769983241; called by muse, varscan2
- OCA2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 110/281 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1456118236, COSV62348236; ClinVar: uncertain significance; called by muse, varscan2
- OCRL | c.2360T>C p.V787A | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as CD972370; called by muse, varscan2
- OLFML1 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs144696887, COSV61402196; called by muse, varscan2
- OR56A1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs139101039, COSV57362853; called by muse, varscan2
- OTOF | c.2782G>A p.G928S (on ENST00000272371 / NM_194248.3; = p.G181S on NM_004802.4) | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs747952633; called by muse, varscan2
- OXGR1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.728); catalogued as rs761797090; called by muse, varscan2
- P3H4 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs781872433; called by muse, varscan2
- PABPC1L | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs201624445; called by muse, varscan2
- PACRG | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs143276239, COSV61304751; called by muse, varscan2
- PALM2AKAP2 | c.478C>T p.R160W (on ENST00000259318 / NM_001136562.3; = p.R391W on NM_007203.5) | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs146218630; called by muse, varscan2
- PARP8 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs376492269; called by muse, varscan2
- PARP9 | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 116/299 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs906290415; called by muse, varscan2
- PBXIP1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs750007221, COSV63777202; called by muse, varscan2
- PCDHA7 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 146/428 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.277); catalogued as rs550090383, COSV65346004; called by muse, varscan2
- PCSK4 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs775122503; called by muse, varscan2
- PDE4DIP | c.4466G>T p.R1489L | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV57720024; called by muse, varscan2
- PDE6B | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs777799273; called by muse, varscan2
- PDE8A | c.1192A>G p.N398D | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV59637453; called by muse, varscan2
- PEAR1 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368688164; called by muse, varscan2
- PGAP3 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs754318839; called by muse, varscan2
- PGAP3 | c.280-2A>G p.X94_splice | Splice Site (SNP) | VAF 31/237 reads (13%) | catalogued as COSV56130217; called by muse, varscan2
- PHKB | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1455480871; called by muse, varscan2
- PIDD1 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as rs201970984, COSV100204206; called by muse, varscan2
- PIK3CD | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs755725121; called by muse, varscan2
- PILRB | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 128/333 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as rs371931442; called by muse, varscan2
- PITPNA | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs369131097; called by muse, varscan2
- PITRM1 | c.1843G>A p.V615M | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs188627057; called by muse, varscan2
- PKDCC | c.1035-6C>T | Splice Region (SNP) | VAF 64/192 reads (33%) | catalogued as rs746449609; called by muse, varscan2
- PLA2G2F | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.043); catalogued as rs148806389, COSV100907906; called by muse, varscan2
- PLCH2 | c.4009C>T p.R1337C | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs759734170, COSV99615680; called by muse, varscan2
- PLCXD1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 126/338 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV58204993; called by muse, varscan2
- PLD5 | c.1388A>G p.Q463R (on ENST00000442594; = p.Q401R on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/250 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.284); catalogued as COSV59132305; called by muse, varscan2
- PLEC | c.541C>T p.Q181* (on ENST00000322810 / NM_201380.4; = p.Q71* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 63/208 reads (30%) | catalogued as COSV100518245; called by muse, varscan2
- PLEKHG2 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1319918473; called by muse, varscan2
- PLEKHG2 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs370716794; called by muse, varscan2
- PLXNA4 | c.3983G>A p.G1328E | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58104286; called by muse, varscan2
- POC1B | c.810G>A p.T270= | Splice Region (SNP) | VAF 58/170 reads (34%) | catalogued as rs748734060, COSV100544143; called by muse, varscan2
- POGLUT3 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs371817425; called by muse, varscan2
- POLE | c.2308G>T p.G770W | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57682911; called by muse, varscan2
- POM121 | c.2261C>T p.A754V (on ENST00000434423; = p.A489V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 187/921 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.395); catalogued as rs1456605273, COSV57513291; called by muse, varscan2
- POMGNT2 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs143892607; called by muse, varscan2
- PPIG | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs145092528; called by muse, varscan2
- PPP1R37 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55523656; called by muse, varscan2
- PPP2R5B | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs977094131; called by muse, varscan2
- PRDM5 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 60/340 reads (18%) | catalogued as COSV99311824; called by muse, varscan2
- PROCA1 | c.469G>A p.A157T (on ENST00000439862 / NM_001366301.1; = p.A129T on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV99972632; called by muse, varscan2
- PRPF8 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs144200305; called by muse, varscan2
- PRR14 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 133/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1314254608, COSV54912949; called by muse, varscan2
- PTGFRN | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV101277368; called by muse, varscan2
- PUDP | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66904380; called by muse, varscan2
- PUF60 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 142/384 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs938236904, COSV57649232; called by muse, varscan2
- PUM1 | c.2452C>T p.R818* | Nonsense Mutation (SNP) | VAF 96/270 reads (36%) | catalogued as COSV57083744; called by muse, varscan2
- PWWP3A | c.1705C>T p.R569W (on ENST00000627377; = p.R568W on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760635708; called by muse, varscan2
- QPRT | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748335998; called by muse, varscan2
- RBM39 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 197/541 reads (36%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.964); catalogued as rs781288675; called by muse, varscan2
- RCCD1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754121446; called by muse, varscan2
- RFLNB | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375866578; called by muse, varscan2
- RFNG | c.318C>T p.G106= | Splice Region (SNP) | VAF 68/181 reads (38%) | catalogued as rs878996722, COSV57648141; called by muse, varscan2
- RGL1 | c.686C>T p.T229M (on ENST00000360851 / NM_001297672.2; = p.T264M on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs368589442; called by muse, varscan2
- RIMKLB | c.699T>C p.G233= | Splice Region (SNP) | VAF 48/100 reads (48%) | catalogued as rs750914842; called by muse, varscan2
- RIPOR3 | c.1694A>G p.E565G | Missense Mutation (SNP) | VAF 112/299 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs769540750, COSV50398813; called by muse, varscan2
- RNF20 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs148632747; called by muse, varscan2
- RPAP1 | c.2986T>C p.Y996H | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58541410; called by muse, varscan2
- RPS26 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs1294448241; called by muse, varscan2
- RRP15 | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs748897447; called by muse, varscan2
- RTCB | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1291033934; called by muse, varscan2
- RTTN | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1478425334; called by muse, varscan2
- RXFP3 | c.1382A>G p.D461G | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1399057207; called by muse, varscan2
- RYR1 | c.8735C>T p.T2912M | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV100615361; called by muse, varscan2
- SALL3 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 63/171 reads (37%) | catalogued as rs751879304, COSV101609972; called by muse, varscan2
- SARDH | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs140650551; called by muse, varscan2
- SARDH | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.234); catalogued as rs760282297, COSV53836094; called by muse, varscan2
- SAYSD1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756967804, COSV57722850; called by muse, varscan2
- SBK2 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs760724693, COSV100705048; called by muse, varscan2
- SBNO2 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs768000819; called by muse, varscan2
- SDAD1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1487696468; called by muse, varscan2
- SECISBP2 | c.2039T>C p.V680A | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1201971963; called by muse, varscan2
- SEMA3E | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773304273, COSV57096799; called by muse, varscan2
- SEMA4C | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539849379, COSV59691127; called by muse, varscan2
- SERPINB1 | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 166/384 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as rs145153494; called by muse, varscan2
- SERPINC1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs750413071; called by muse, varscan2
- SETD1A | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as rs915671434, COSV52691218; called by muse, varscan2
- SETD2 | c.4567C>A p.R1523S | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57433049; called by muse, varscan2
- SETX | c.3881G>A p.R1294H | Missense Mutation (SNP) | VAF 161/452 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777857355, COSV56385119; called by muse, varscan2
- SIK3 | c.2617C>T p.R873C (on ENST00000445177 / NM_001366686.2; = p.R831C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs768087803, COSV52608420; called by muse, varscan2
- SLC16A2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 74/98 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as CM090716, COSV52082451, COSV52088806; called by muse, varscan2
- SLC16A8 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 119/277 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1466908128, COSV57635899; called by muse, varscan2
- SLC19A1 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs199502402; called by muse, varscan2
- SLC2A8 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753755259; called by muse, varscan2
- SLC44A5 | c.863A>G p.H288R | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV63769732; called by muse, varscan2
- SLC4A11 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 118/334 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs751358233, COSV66262630; called by muse, varscan2
- SLC66A1 | c.618C>T p.N206= | Splice Region (SNP) | VAF 110/300 reads (37%) | catalogued as rs748467022; called by muse, varscan2
- SLC6A11 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs757265540, COSV54397819; called by muse, varscan2
- SLFN13 | c.2222T>C p.I741T | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs529408632; called by muse, varscan2
- SMG1 | c.7259A>G p.D2420G | Missense Mutation (SNP) | VAF 124/382 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67175506; called by muse, varscan2
- SMOC2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 125/336 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs201154391, COSV62433319; called by muse, varscan2
- SMTN | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 139/382 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1204043679; called by muse, varscan2
- SOHLH1 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs550754812; called by muse, varscan2
- SPHKAP | c.4895C>T p.A1632V (on ENST00000392056 / NM_001142644.2; = p.A1603V on NM_030623.3) | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60870085; called by muse, varscan2
- SPIRE1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 90/276 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs372489121, COSV59151677; called by muse, varscan2
- SPTBN5 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1238021477, COSV58016159; called by muse, varscan2
- SRCIN1 | c.1574C>T p.P525L (on ENST00000621492; = p.P491L on NM_025248.3) | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs745846775; called by muse, varscan2
- SRMS | c.1131C>T p.D377= | Splice Region (SNP) | VAF 84/208 reads (40%) | catalogued as rs55838540; called by muse, varscan2
- STK32C | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV53843783; called by muse, varscan2
- SUGCT | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59361152; called by muse, varscan2
- SYCP2 | c.3820A>G p.T1274A | Missense Mutation (SNP) | VAF 96/288 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV62766536; called by muse, varscan2
- SYNE1 | c.1774G>A p.A592T (on ENST00000367255 / NM_182961.4; = p.A599T on NM_033071.3) | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs747150703; called by muse, varscan2
- SYNPR | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 118/339 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs535191041; called by muse, varscan2
- SYT2 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771191387; called by muse, varscan2
- TAF10 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 82/254 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100196206; called by muse, varscan2
- TANC1 | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777299338, COSV55082707, COSV55088606; called by muse, varscan2
- TAS2R10 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184682737, COSV53700981; called by muse, varscan2
- TAT | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs775311489; called by muse, varscan2
- TBC1D10C | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1300930874; called by muse, varscan2
- TBC1D17 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); catalogued as rs376341286; called by muse, varscan2
- TBC1D8 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558638484, COSV100964495, COSV65215365; called by muse, varscan2
- TCN2 | c.428-2A>G p.X143_splice | Splice Site (SNP) | VAF 24/203 reads (12%) | catalogued as COSV53191097; called by muse, varscan2
- TDP2 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs372058337; called by muse, varscan2
- TELO2 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 63/205 reads (31%) | catalogued as rs1401617204, COSV51979723; called by muse, varscan2
- TEX13C | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs533141129; called by muse, varscan2
- TEX15 | c.1825A>G p.M609V (on ENST00000256246; = p.M992V on NM_001350162.2) | Missense Mutation (SNP) | VAF 73/445 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375807083; called by muse, varscan2
- TFAP2E | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1223863421; called by muse, varscan2
- TGIF1 | c.710C>T p.A237V (on ENST00000330513 / NM_001374396.1; = p.A257V on NM_003244.4) | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100394983; called by muse, varscan2
- THEM6 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs184540082; called by muse, varscan2
- THSD4 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as rs768392988; called by muse, varscan2
- TLN2 | c.4681C>T p.R1561C | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.433); catalogued as rs369554074; called by muse, varscan2
- TLR2 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as rs1459674700; called by muse, varscan2
- TMEM256 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1297198552; called by muse, varscan2
- TMEM259 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754010810; called by muse, varscan2
- TNIP1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 149/366 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs762262775, COSV100161631; called by muse, varscan2
- TNN | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53421744; called by muse, varscan2
- TNNT3 | c.278G>A p.R93Q (on ENST00000397301 / NM_001367846.1; = p.R82Q on NM_006757.4) | Missense Mutation (SNP) | VAF 69/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415991336; called by muse, varscan2
- TOP2A | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 55/372 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV70733564; called by muse, varscan2
- TOPAZ1 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs1459664054, COSV59067916; called by muse, varscan2
- TP63 | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53218754; called by muse, varscan2
- TPO | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 62/172 reads (36%) | catalogued as rs763459820, CM076569, COSV61093527; called by muse, varscan2
- TPR | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 150/384 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1337881719; called by muse, varscan2
- TRAPPC12 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs759458791, COSV100161080; called by muse, varscan2
- TRAPPC6B | c.116T>C p.M39T | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs769631954; called by muse, varscan2
- TSKS | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs549647891, COSV55877498; called by muse, varscan2
- TSPYL5 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV59071820, COSV59071974; called by muse, varscan2
- TTBK1 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 94/268 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs953189053; called by muse, varscan2
- TTLL9 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs770951589, COSV60595004; called by muse, varscan2
- TTN | c.4249A>G p.M1417V (on ENST00000591111; = p.M1371V on NM_003319.4) | Missense Mutation (SNP) | VAF 172/472 reads (36%) | PolyPhen benign (0); catalogued as rs1187409316; called by muse, varscan2
- TUBB6 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs11548178, COSV100480968; called by muse, varscan2
- TUBGCP4 | c.1504C>T p.R502C (on ENST00000260383 / NM_001286414.3; = p.R501C on NM_014444.5) | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV53019142; called by muse, varscan2
- TUBGCP6 | c.5132G>A p.R1711H | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs373160527; called by muse, varscan2
- TUT1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.884); catalogued as rs146236984; called by muse, varscan2
- UBQLN2 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750074034, COSV100592709; called by muse, varscan2
- UBR5 | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.885); catalogued as rs778419766, COSV99642722; called by muse, varscan2
- UNC13B | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs55744473; called by muse, varscan2
- UNC80 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs981095852, COSV55893549; called by muse, varscan2
- UNC80 | c.8555G>A p.R2852H | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs772317430; called by muse, varscan2
- UROC1 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373958192; called by muse, varscan2
- USH2A | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs111033272, CS042173; called by muse, varscan2
- USP19 | c.3610C>T p.R1204C | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441755116, COSV67350023; called by muse, varscan2
- USP35 | c.2587T>C p.Y863H | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60871522; called by muse, varscan2
- UTP4 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 110/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760350216; called by muse, varscan2
- WIPF1 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 127/370 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as rs759804410, COSV55821211; called by muse, varscan2
- WNK3 | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 127/182 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs868955784, COSV63616569; called by muse, varscan2
- WWP1 | c.70+2T>C p.X24_splice | Splice Site (SNP) | VAF 25/252 reads (10%) | catalogued as rs753489450; called by muse, varscan2
- XDH | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs61731081, COSV65146915; called by muse, varscan2
- XRN1 | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.386); catalogued as rs1213312515, COSV99377542; called by muse, varscan2
- ZAN | c.4537C>T p.R1513C | Missense Mutation (SNP) | VAF 106/284 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1353358307, COSV61818130; called by muse, varscan2
- ZBBX | c.2372T>C p.V791A | Missense Mutation (SNP) | VAF 105/326 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV56795002; called by muse, varscan2
- ZC3H12A | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565672584; called by muse, varscan2
- ZFHX4 | c.5870A>G p.N1957S | Missense Mutation (SNP) | VAF 62/417 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.763); catalogued as rs1365373571; called by muse, varscan2
- ZHX1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 154/396 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV52877904; called by muse, varscan2
- ZMYM5 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 62/591 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61988120, COSV61989086; called by muse, varscan2
- ZNF12 | c.1816G>A p.E606K (on ENST00000405858 / NM_016265.4; = p.E568K on NM_006956.3) | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as rs1215537665; called by muse, varscan2
- ZNF202 | c.1825G>A p.V609I | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs781278559, COSV60248377; called by muse, varscan2
- ZNF263 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1363167808; called by muse, varscan2
- ZNF415 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs548389733; called by muse, varscan2
- ZNF442 | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV54422037; called by muse, varscan2
- ZNF469 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1455652900; called by muse, varscan2
- ZNF536 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139989586, COSV62829439; called by muse, varscan2
- ZNF653 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs752213620; called by muse, varscan2
- ZNF668 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs202118331, COSV56212806; called by muse, varscan2
- ZNF707 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 115/340 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as rs370404313; called by muse, varscan2
- ZNF777 | c.2134C>A p.H712N | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56099296; called by muse, varscan2
- ZP1 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs767981457, COSV53923677; called by muse, varscan2
- ABCA9 | c.3692T>G p.L1231R | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, varscan2
- ABCB1 | c.1034T>G p.V345G | Missense Mutation (SNP) | VAF 122/376 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, varscan2
- ABI3 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, varscan2
- ACSBG2 | c.739-2A>G p.X247_splice | Splice Site (SNP) | VAF 15/142 reads (11%) | called by muse, varscan2
- ADAMTS5 | c.2652G>A p.W884* | Nonsense Mutation (SNP) | VAF 98/298 reads (33%) | called by muse, varscan2
- ADGRA3 | c.1570T>C p.Y524H | Missense Mutation (SNP) | VAF 123/315 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- ADGRB1 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 60/246 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, varscan2
- ADRB2 | c.1030A>G p.R344G | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, varscan2
- AFAP1L1 | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 144/406 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); called by muse, varscan2
- AGFG2 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- AGL | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- AHCTF1 | c.2344A>G p.T782A (on ENST00000366508; = p.T756A on NM_015446.5) | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, varscan2
- AJM1 | c.2335T>C p.Y779H | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, varscan2
- AL008638.2 | n.410+2T>C | Splice Site (SNP) | VAF 34/221 reads (15%) | called by muse, varscan2
- ALS2 | c.994T>G p.S332A | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, varscan2
- ANKIB1 | c.2366A>G p.D789G | Missense Mutation (SNP) | VAF 106/295 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.411); called by muse, varscan2
- ANKRD12 | c.5605A>G p.T1869A | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- AOC3 | c.2011G>T p.G671* | Nonsense Mutation (SNP) | VAF 72/166 reads (43%) | called by muse, varscan2
- APC | c.4780C>G p.P1594A | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, varscan2
- APOA1 | c.-20-2A>C | Splice Site (SNP) | VAF 64/196 reads (33%) | called by muse, varscan2
- ARID3B | c.240A>C p.Q80H | Missense Mutation (SNP) | VAF 64/474 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, varscan2
- ARID4B | c.2535G>T p.K845N | Missense Mutation (SNP) | VAF 198/568 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, varscan2
- ASB2 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.115); called by muse, varscan2
- ASIC4 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, varscan2
- ASXL2 | c.2134G>T p.G712* | Nonsense Mutation (SNP) | VAF 88/252 reads (35%) | called by muse, varscan2
- ATIC | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ATN1 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 176/478 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- ATP13A1 | c.2534A>C p.K845T | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ATP1A4 | c.2776A>G p.T926A | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, varscan2
- ATP5F1D | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.074); called by muse, varscan2
- ATP5PF | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, varscan2
- ATP8A2 | c.1611G>T p.K537N | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, varscan2
- AXIN1 | c.1681A>T p.S561C | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, varscan2
- B3GAT1 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- BAIAP2L1 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- BAZ2A | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- BCL9L | c.4010G>A p.S1337N | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, varscan2
- BDKRB2 | c.589A>C p.T197P | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, varscan2
- BPIFC | c.364T>C p.S122P | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, varscan2
- C10orf71 | c.2378A>C p.N793T | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, varscan2
- C11orf95 | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- C16orf70 | c.1016A>G p.D339G | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.096); called by muse, varscan2
- C16orf96 | c.2768C>T p.T923I | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- C6orf163 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, varscan2
- C7orf33 | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.54); called by muse, varscan2
- CACNB3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 46/273 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, varscan2
- CARNMT1 | c.731+2T>C p.X244_splice | Splice Site (SNP) | VAF 34/196 reads (17%) | called by muse, varscan2
- CC2D2B | c.174+2T>C p.X58_splice (on ENST00000646931 / NM_001349008.3; = p.X50_splice on NM_001130446.3) | Splice Site (SNP) | VAF 70/200 reads (35%) | called by muse, varscan2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 22/198 reads (11%) | called by muse, varscan2
- CCDC183 | c.192+2T>C p.X64_splice | Splice Site (SNP) | VAF 28/80 reads (35%) | called by muse, varscan2
- CCDC183 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.037); called by muse, varscan2
- CCDC8 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 110/342 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CD55 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, varscan2
- CDC42BPG | c.4277T>C p.M1426T | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, varscan2
- CDC6 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CDH11 | c.52T>C p.C18R | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, varscan2
- CDK5RAP2 | c.1601C>A p.P534Q | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); called by muse, varscan2
- CEACAM7 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- CEP126 | c.1187A>G p.D396G | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.159); called by muse, varscan2
- CEP290 | c.4012A>G p.T1338A | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CEP295 | c.6370A>G p.T2124A | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, varscan2
- CEP295NL | c.1592A>G p.E531G | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.339); called by muse, varscan2
- CEP85 | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CERS2 | c.173+2T>C p.X58_splice | Splice Site (SNP) | VAF 160/454 reads (35%) | called by muse, varscan2
- CFAP70 | c.2890A>G p.N964D | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, varscan2
- CHCHD7 | c.153+2T>C p.X51_splice (on ENST00000355315 / NM_001011671.3; = p.X63_splice on NM_024300.4) | Splice Site (SNP) | VAF 59/185 reads (32%) | called by muse, varscan2
- CHRNG | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 98/244 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.296); called by muse, varscan2
- CHST7 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, varscan2
- CLEC4M | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CLNK | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.091); called by muse, varscan2
- COG6 | c.1931T>A p.I644N | Missense Mutation (SNP) | VAF 58/400 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- COL4A2 | c.2641G>A p.G881S | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- COL5A1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 102/310 reads (33%) | called by muse, varscan2
- COL6A3 | c.8302T>G p.F2768V | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, varscan2
- COL6A3 | c.6641G>A p.G2214D | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.036); called by muse, varscan2
- COL6A6 | c.4349A>G p.N1450S | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- CSRNP2 | c.1499A>G p.H500R | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- CTPS1 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.217); called by muse, varscan2
- CYB5R2 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- DAGLB | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, varscan2
- DDX31 | c.722T>C p.L241S | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, varscan2
- DEPDC5 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- DHX36 | c.2584A>T p.K862* | Nonsense Mutation (SNP) | VAF 36/214 reads (17%) | called by muse, varscan2
- DMP1 | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- DNA2 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 109/278 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, varscan2
- DNAH11 | c.11202+2T>C p.X3734_splice | Splice Site (SNP) | VAF 27/263 reads (10%) | called by muse, varscan2
- DNAH2 | c.12170T>C p.L4057P | Missense Mutation (SNP) | VAF 70/352 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- DNAH8 | c.12634G>T p.G4212C | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DOT1L | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, varscan2
- EEF1A1 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.24); called by muse, varscan2
- EIF3I | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 152/412 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- ELF2 | c.742A>G p.K248E (on ENST00000379550 / NM_001331036.2; = p.K188E on NM_006874.4) | Missense Mutation (SNP) | VAF 150/366 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, varscan2
- EP300 | c.3415T>C p.Y1139H | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- EPHA1 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- EPHA7 | c.2882+2T>A p.X961_splice | Splice Site (SNP) | VAF 52/221 reads (24%) | called by muse, varscan2
- EPHB3 | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, varscan2
- EPHX4 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, varscan2
- EPS8L3 | c.461+2T>C p.X154_splice | Splice Site (SNP) | VAF 32/230 reads (14%) | called by muse, varscan2
- ERBB2 | c.1737+2T>C p.X579_splice | Splice Site (SNP) | VAF 28/174 reads (16%) | called by muse, varscan2
- ERC1 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.459); called by muse, varscan2
- ERFE | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- ESRP1 | c.520T>C p.S174P | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, varscan2
- ESYT1 | c.2199-1G>T p.X733_splice | Splice Site (SNP) | VAF 62/180 reads (34%) | called by muse, varscan2
- EVI2A | c.605T>G p.L202R | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, varscan2
- EVI5 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, varscan2
- EXOC6B | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 65/214 reads (30%) | called by muse, varscan2
- EXOSC1 | c.385T>A p.L129M | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, varscan2
- FAM118B | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.036); called by muse, varscan2
- FAM189B | c.712C>A p.L238M | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, varscan2
- FAM76A | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.998); called by muse, varscan2
- FASN | c.1741T>G p.S581A | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FBXO10 | c.718C>A p.L240M | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, varscan2
- FDPS | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- FGF16 | c.378+2T>C p.X126_splice | Splice Site (SNP) | VAF 51/86 reads (59%) | called by muse, varscan2
- FHAD1 | c.1859A>T p.E620V | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FN1 | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FOXC1 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, varscan2
- FRMPD1 | c.4301A>G p.D1434G | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- FRMPD4 | c.1052T>A p.I351N | Missense Mutation (SNP) | VAF 84/122 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, varscan2
- FUT10 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- FZR1 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, varscan2
- GABPB2 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GABRB1 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- GAREM2 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- GARS1 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 132/350 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- GCM2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 35/235 reads (15%) | called by muse, varscan2
- GJB7 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 120/298 reads (40%) | called by muse, varscan2
- GNPAT | c.1573T>C p.F525L | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); called by muse, varscan2
- GOLGA1 | c.1677G>T p.E559D | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.15); called by muse, varscan2
- GOLGA8T | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 48/383 reads (13%) | called by muse, varscan2
- GPR108 | c.1535A>G p.E512G (on ENST00000264080 / NM_001080452.1; = p.E270G on NM_020171.2) | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, varscan2
- GPRC5A | c.608T>C p.F203S | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.551); called by muse, varscan2
- GREB1L | c.4087A>G p.S1363G | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- GRIN1 | c.1042T>C p.F348L | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.123); called by muse, varscan2
- GRPEL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, varscan2
- GZF1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 144/376 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.903); called by muse, varscan2
- GZF1 | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, varscan2
- H2BC18 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); called by muse, varscan2
- H6PD | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.1); called by muse, varscan2
- HGS | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 92/490 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- HINFP | c.523+2T>C p.X175_splice | Splice Site (SNP) | VAF 72/185 reads (39%) | called by muse, varscan2
- HLCS | c.1518A>C p.K506N | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, varscan2
- HNRNPM | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | called by muse, varscan2
- HP | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, varscan2
- HUWE1 | c.12833T>A p.I4278N | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- IARS1 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 99/274 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, varscan2
- IFNL3 | c.262A>T p.R88W | Missense Mutation (SNP) | VAF 66/424 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- IHO1 | c.1148G>T p.R383M | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, varscan2
- IKZF2 | c.139+2T>C p.X47_splice | Splice Site (SNP) | VAF 90/248 reads (36%) | called by muse, varscan2
- IL4 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, varscan2
- IMMT | c.1307A>T p.K436I | Missense Mutation (SNP) | VAF 122/371 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.219); called by muse, varscan2
- IPCEF1 | c.37-2A>G p.X13_splice | Splice Site (SNP) | VAF 14/97 reads (14%) | called by muse, varscan2
- IRS2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, varscan2
- ITGA6 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.103); called by muse, varscan2
- JPH1 | c.961T>A p.F321I | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- KATNAL2 | c.809T>C p.V270A (on ENST00000356157 / NM_001353899.1; = p.V198A on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KCNAB3 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 52/402 reads (13%) | called by muse, varscan2
- KCNJ10 | c.1082T>C p.L361S | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.38); called by muse, varscan2
- KCTD13 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 30/157 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); called by muse, varscan2
- KDM6B | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, varscan2
- KIAA1586 | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.657); called by muse, varscan2
- KIAA1614 | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- KIF21A | c.1379A>G p.Q460R | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, varscan2
- KIF26B | c.3376A>G p.T1126A | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, varscan2
- KLHDC7A | c.2296A>G p.T766A | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, varscan2
- KLHL34 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 63/97 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, varscan2
- KMT2B | c.3031C>T p.R1011W | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- KPRP | c.251A>G p.Q84R | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); called by muse, varscan2
- KRT32 | c.551+2T>C p.X184_splice | Splice Site (SNP) | VAF 66/174 reads (38%) | called by muse, varscan2
- LARP6 | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 90/260 reads (35%) | called by muse, varscan2
- LCN8 | c.401-5C>A | Splice Region (SNP) | VAF 74/206 reads (36%) | called by muse, varscan2
- LCOR | c.1172G>A p.G391D | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LINGO4 | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.289); called by muse, varscan2
- LIPF | c.106-2A>G p.X36_splice | Splice Site (SNP) | VAF 44/112 reads (39%) | called by muse, varscan2
- LMNB2 | c.264+2T>C p.X88_splice | Splice Site (SNP) | VAF 77/178 reads (43%) | called by muse, varscan2
- LRBA | c.7172T>C p.V2391A | Missense Mutation (SNP) | VAF 105/260 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LRIG3 | c.1810T>C p.S604P | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- LRRC15 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); called by muse, varscan2
- LRRC66 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, varscan2
- LRRIQ1 | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, varscan2
- LRRIQ1 | c.3400C>T p.P1134S | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, varscan2
- LRRN3 | c.1879A>T p.T627S | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, varscan2
- LSM11 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, varscan2
- LTN1 | c.2680A>G p.T894A | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, varscan2
- LUZP2 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, varscan2
- LZTS2 | c.1323G>T p.W441C | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAMLD1 | c.1875G>T p.Q625H | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.568); called by muse, varscan2
- MAN2A1 | c.3253G>T p.G1085W | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, varscan2
- MAN2B2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by muse, varscan2
- MAP1A | c.7993C>T p.P2665S | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, varscan2
- MAP1B | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MAP1B | c.7159G>A p.V2387M | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MAST2 | c.5068A>C p.T1690P | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, varscan2
- MAST4 | c.5410A>G p.T1804A (on ENST00000403625 / NM_001164664.2; = p.T1615A on NM_015183.3) | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MAST4 | c.6626A>G p.D2209G (on ENST00000403625 / NM_001164664.2; = p.D2020G on NM_015183.3) | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- MAU2 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.123); called by muse, varscan2
- MED14 | c.1670T>C p.V557A | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, varscan2
- METAP1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 144/392 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.052); called by muse, varscan2
- MILR1 | c.524A>G p.D175G | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.019); called by muse, varscan2
- MINDY1 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, varscan2
- MIS18BP1 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, varscan2
- MKRN1 | c.1018T>C p.F340L | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.275); called by muse, varscan2
- MLXIPL | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MMRN1 | c.1636A>T p.M546L | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, varscan2
- MOB1A | c.556T>G p.F186V | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- MPRIP | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.156); called by muse, varscan2
- MUC16 | c.28690A>G p.M9564V | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.009); called by muse, varscan2
- MUC5B | c.10316T>C p.L3439P | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, varscan2
- MUC5B | c.11626A>G p.T3876A | Missense Mutation (SNP) | VAF 191/464 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, varscan2
- MYH7 | c.3059T>C p.L1020P | Missense Mutation (SNP) | VAF 140/390 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MYO5C | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.498); called by muse, varscan2
- MYT1 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, varscan2
- N4BP2L2 | c.1474-3T>C | Splice Region (SNP) | VAF 48/248 reads (19%) | called by muse, varscan2
- NAA35 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.247); called by muse, varscan2
- NADK | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, varscan2
- NBPF10 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.024); called by muse, varscan2
- NDUFS8 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.024); called by muse, varscan2
- NEK1 | c.551+2T>C p.X184_splice | Splice Site (SNP) | VAF 32/150 reads (21%) | called by muse, varscan2
- NEU1 | c.707A>G p.H236R | Missense Mutation (SNP) | VAF 111/284 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); called by muse, varscan2
- NFATC1 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, varscan2
- NFYC | c.1301A>G p.D434G (on ENST00000308733 / NM_001308114.1; = p.D311G on NM_014223.5) | Missense Mutation (SNP) | VAF 88/166 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, varscan2
- NKAP | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, varscan2
- NLGN4X | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 108/152 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, varscan2
- NSD1 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 102/330 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, varscan2
- NSD3 | c.4034A>G p.Y1345C | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NUCKS1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, varscan2
- NUMB | c.1891A>G p.T631A (on ENST00000355058; = p.T620A on NM_003744.5) | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, varscan2
- NUP155 | c.1562G>T p.R521M (on ENST00000231498 / NM_153485.3; = p.R462M on NM_004298.4) | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, varscan2
- OGDH | c.695A>G p.Q232R | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, varscan2
- OLFM2 | c.580+2T>C p.X194_splice | Splice Site (SNP) | VAF 43/130 reads (33%) | called by muse, varscan2
- OR1N1 | c.715T>G p.C239G | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR4C5 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, varscan2
- OR9A4 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 120/315 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PABPC5 | c.671C>A p.P224Q | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- PARD6G | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- PATL1 | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PCDH10 | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- PCDHGA11 | c.397A>G p.S133G | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, varscan2
- PFKP | c.2051A>G p.N684S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, varscan2
- PHF14 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- PHF2 | c.2335T>C p.Y779H | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, varscan2
- PKD1 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, varscan2
- PLA2G6 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.217); called by muse, varscan2
- PLCH2 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PLXNA2 | c.2672C>G p.A891G | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, varscan2
- PLXND1 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PNKD | c.830C>G p.T277S | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.315); called by muse, varscan2
- POLR1A | c.2785A>G p.M929V | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, varscan2
- POLR1E | c.1055G>T p.R352M (on ENST00000377792 / NM_001282766.1; = p.R290M on NM_022490.4) | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, varscan2
- POPDC2 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, varscan2
- PPFIBP2 | c.64+2T>C p.X22_splice | Splice Site (SNP) | VAF 54/150 reads (36%) | called by muse, varscan2
- PPP1R26 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.036); called by muse, varscan2
- PRDM1 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.062); called by muse, varscan2
- PRDM6 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, varscan2
- PREX2 | c.4154G>A p.S1385N | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, varscan2
- PRKCI | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 86/476 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- PRRG3 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.089); called by muse, varscan2
- PRSS38 | c.149-1G>A p.X50_splice | Splice Site (SNP) | VAF 78/210 reads (37%) | called by muse, varscan2
- PSD4 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- PSMD14 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, varscan2
- PSMD7 | c.285C>G p.Y95* | Nonsense Mutation (SNP) | VAF 114/310 reads (37%) | called by muse, varscan2
- PTPN22 | c.750G>A p.G250= | Splice Region (SNP) | VAF 18/128 reads (14%) | called by muse, varscan2
- RAB11FIP1 | c.2197A>G p.S733G | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, varscan2
- RAB40A | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RAB8B | c.532-2A>T p.X178_splice | Splice Site (SNP) | VAF 50/160 reads (31%) | called by muse, varscan2
- RABGAP1L | c.2252C>A p.A751D | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, varscan2
- RBCK1 | c.679C>A p.P227T (on ENST00000356286 / NM_031229.4; = p.P185T on NM_006462.6) | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- RFX2 | c.2114G>A p.G705D | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, varscan2
- RGS12 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, varscan2
- RGS6 | c.482G>T p.R161M | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- RIT1 | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 83/269 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); called by muse, varscan2
- RNF112 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.994); called by muse, varscan2
- RNF214 | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.079); called by muse, varscan2
- ROPN1 | c.396+3A>G | Splice Region (SNP) | VAF 76/332 reads (23%) | called by muse, varscan2
- RPF2 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- RPL10 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.341); called by muse, varscan2
- RPS6KA2 | c.1805A>G p.Y602C | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- RRM1 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 73/226 reads (32%) | called by muse, varscan2
- RYR3 | c.5234A>T p.Q1745L | Missense Mutation (SNP) | VAF 120/337 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.175); called by muse, varscan2
- SARDH | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SCAMP2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.042); called by muse, varscan2
- SCARA5 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- SCARB1 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, varscan2
- SCGN | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 98/136 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, varscan2
- SCNN1D | c.419+2T>A p.X140_splice (on ENST00000338555; = p.X304_splice on NM_001130413.4) | Splice Site (SNP) | VAF 22/148 reads (15%) | called by muse, varscan2
- SDK1 | c.632A>C p.N211T | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, varscan2
- SECISBP2 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, varscan2
- SERPINB1 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, varscan2
- SETBP1 | c.646A>G p.S216G | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.124); called by muse, varscan2
- SF1 | c.1102T>C p.W368R | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SFMBT1 | c.1631T>C p.L544S | Missense Mutation (SNP) | VAF 70/403 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SGSM1 | c.3133G>A p.G1045R (on ENST00000400359 / NM_001039948.4; = p.G984R on NM_133454.3) | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SH2D7 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, varscan2
- SHROOM1 | c.313G>T p.G105* | Nonsense Mutation (SNP) | VAF 82/226 reads (36%) | called by muse, varscan2
- SHTN1 | c.1356A>G p.I452M | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, varscan2
- SIPA1L3 | c.2715G>T p.K905N | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, varscan2
- SLC16A3 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.962); called by muse, varscan2
- SLC16A9 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 100/314 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC16A9 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLC22A18 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, varscan2
- SLC25A47 | c.610T>G p.C204G | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, varscan2
- SLC25A52 | c.497A>G p.N166S (on ENST00000672005; = p.N156S on NM_001034172.4) | Missense Mutation (SNP) | VAF 68/472 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.249); called by muse, varscan2
- SLC2A11 | c.539A>T p.E180V (on ENST00000345044 / NM_001024938.4; = p.E187V on NM_030807.5) | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, varscan2
- SLC39A3 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, varscan2
- SLC4A9 | c.2219T>C p.I740T (on ENST00000507527 / NM_001258428.2; = p.I716T on NM_031467.3) | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC6A13 | c.1747T>G p.S583A | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, varscan2
- SLC6A5 | c.1063A>G p.T355A | Missense Mutation (SNP) | VAF 114/376 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.129); called by muse, varscan2
- SLC7A6 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.141); called by muse, varscan2
- SLITRK4 | c.1170G>T p.K390N | Missense Mutation (SNP) | VAF 138/184 reads (75%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, varscan2
- SMARCA2 | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- SMARCA4 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, varscan2
- SMC1B | c.2783A>G p.N928S | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.46); called by muse, varscan2
- SNAPIN | c.190+2T>C p.X64_splice | Splice Site (SNP) | VAF 50/156 reads (32%) | called by muse, varscan2
- SNX18 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 107/305 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, varscan2
- SPDL1 | c.698A>T p.N233I | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
640 further variants in this file (75 protein-altering or splice-affecting, 324 silent, 241 other) are not listed here.
